Somatic mutation profile of tumor specimen TCGA-A3-3370-01A (aliquot TCGA-A3-3370-01A-02D-1421-08) from TCGA case TCGA-A3-3370, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 48.2 years (17,621 days).
Specimen TCGA-A3-3370-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfd182e2-863d-470e-bbd4-a8779971fd00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3370-11A (Solid Tissue Normal), aliquot TCGA-A3-3370-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de84b092-6169-4dfc-9849-3ba3ee97e80f

The open-access MAF lists 41 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Nonsense Mutation 3, Frame Shift Del 1, Frame Shift Ins 1, Splice Region 1, 5'Flank 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALS2 | c.3274A>G p.K1092E | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV51883926; called by muse, mutect2, varscan2
- AOC2 | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV53198317; called by muse, mutect2, varscan2
- BTG1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV55458089; called by muse, mutect2, varscan2
- C2orf78 | c.2378A>C p.Q793P | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.189); catalogued as rs760419798, COSV68516331; called by muse, mutect2, varscan2
- CACNG3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.324); catalogued as rs868820485, COSV50063824; called by muse, mutect2, varscan2
- CCDC40 | c.2261T>A p.L754H | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as COSV66472656; called by muse, mutect2, varscan2
- CLTC | c.1054G>A p.A352T | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52244742; called by muse, mutect2, varscan2
- DDC | c.277A>G p.M93V | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as rs1190938278, COSV63563594; called by muse, mutect2, varscan2
- DMXL2 | c.770T>G p.L257* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | catalogued as COSV51840604; called by muse, mutect2, varscan2
- KMT2C | c.5641G>C p.V1881L | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51285847; called by muse, mutect2, varscan2
- LRP1B | c.10417A>G p.K3473E | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1206348269, COSV67185225; called by muse, mutect2, varscan2
- MRPL15 | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52636862; called by muse, mutect2, varscan2
- MSN | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV64303161; called by muse, varscan2
- NLRC5 | c.1457C>G p.A486G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs1004693288, COSV52648855; called by muse, mutect2, varscan2
- OR4K1 | c.148T>A p.S50T | Missense Mutation (SNP) | VAF 27/344 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV53458754; called by muse, mutect2
- OR4K1 | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53458768; called by muse, mutect2, varscan2
- PI16 | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs750564019, COSV65447906; called by muse, mutect2, varscan2
- POLE | c.4425G>C p.Q1475H | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV57673947; called by muse, mutect2, varscan2
- PRDX1 | c.43T>C p.F15L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV53112819; called by muse, mutect2, varscan2
- REPS1 | c.1971G>A p.P657= (on ENST00000450536 / NM_001286611.2; = p.P656= on NM_031922.4) | Splice Region (SNP) | VAF 9/69 reads (13%) | catalogued as COSV57808640, COSV57813531; called by muse, mutect2, varscan2
- RSU1 | c.695A>T p.H232L | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV61708785; called by muse, mutect2
- SCAF4 | c.3358A>T p.K1120* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as COSV54255483; called by muse, mutect2, varscan2
- SLC23A1 | c.1699G>T p.V567F | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV54524814; called by muse, mutect2, varscan2
- SLC25A4 | c.608C>G p.P203R | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV55668364; called by muse, mutect2, varscan2
- SLC2A10 | c.1343T>A p.F448Y | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV63713677; called by muse, mutect2, varscan2
- SNX18 | c.795T>A p.Y265* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as COSV57987285, COSV57987313; called by muse, mutect2, varscan2
- SORBS1 | c.1708T>C p.F570L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV53353056; called by muse, mutect2, varscan2
- TBCK | c.1247G>A p.S416N (on ENST00000273980 / NM_001163436.4; = p.S353N on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as rs1330166927, COSV56751849; called by muse, mutect2, varscan2
- TIAM1 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV54537099; called by muse, mutect2
- USP9X | c.7657C>G p.Q2553E | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as COSV61065699; called by muse, mutect2, varscan2
- AP4E1 | c.1968_1970del p.L657del | In Frame Del (DEL) | VAF 4/43 reads (9%) | called by mutect2, varscan2
- GPR155 | c.51dup p.K18Qfs*12 | Frame Shift Ins (INS) | VAF 15/106 reads (14%) | called by mutect2, pindel, varscan2
- ZNF2 | c.1199del p.H400Lfs*38 (on ENST00000611147 / NM_001291605.2; = p.H387Lfs*38 on NM_021088.4) | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- AMN | c.246A>T p.G82= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV54486039; called by muse, mutect2, varscan2
- COMMD9 | c.138A>C p.T46= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV54671871; called by muse, mutect2, varscan2
- LRRC8B | c.1506C>T p.I502= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV58372982; called by muse, mutect2, varscan2
- LYSMD4 | c.681G>A p.L227= (on ENST00000409796 / NM_001284417.2; = p.L228= on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/162 reads (22%) | catalogued as rs150607972; called by muse, mutect2, varscan2
- OSBPL10 | c.1038C>A p.T346= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV67335976; called by muse, mutect2, varscan2
- SLFN11 | c.2523A>G p.A841= | Silent (SNP) | VAF 39/159 reads (25%) | catalogued as rs748261086, COSV57697346; called by muse, mutect2, varscan2
- ALKBH1 | c.*2A>G | 3'UTR (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99380464; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505494 T>C | 5'Flank (SNP) | VAF 19/81 reads (23%) | called by muse, mutect2, varscan2
